Somatic mutation profile of tumor specimen TCGA-CR-7394-01A (aliquot TCGA-CR-7394-01A-11D-2012-08) from TCGA case TCGA-CR-7394, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 70.0 years (25,581 days).
Specimen TCGA-CR-7394-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8255f919-4757-4c8d-b917-992183a48179.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-7394-10A (Blood Derived Normal), aliquot TCGA-CR-7394-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/239db0f3-6c70-4ed9-aca2-df0abe49665e

The open-access MAF lists 144 somatic variants for this specimen: 99 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 41, Nonsense Mutation 8, 3'Flank 1, Intron 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.330G>A p.W110* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | hotspot (GDC flag); catalogued as rs121913389, CM060208, COSV58682827, COSV58708986; ClinVar: likely pathogenic; called by mutect2, varscan2
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAP1 | c.2005C>G p.R669G | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.297); catalogued as COSV50143899; called by muse, mutect2
- ACSM2B | c.1347C>G p.I449M | Missense Mutation (SNP) | VAF 15/292 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.284); catalogued as COSV100312963; called by muse, mutect2
- ALCAM | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1559825257, COSV100065251; called by muse, mutect2
- APOC1 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs760666016, COSV99377230; called by muse, mutect2
- ARHGAP45 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.92); catalogued as rs1391916933, COSV100490938; called by muse, mutect2
- ARID1B | c.1907A>G p.Y636C | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs749173157, COSV99270657; called by muse, mutect2, varscan2
- ARMC5 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1048994571, COSV51658463; called by muse, mutect2, varscan2
- BMI1 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV100936438; called by muse, mutect2
- CCDC125 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 15/211 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.804); catalogued as COSV101143681; called by muse, mutect2
- CCDC87 | c.1965G>A p.W655* | Nonsense Mutation (SNP) | VAF 10/107 reads (9%) | catalogued as COSV100040094; called by muse, mutect2
- CD180 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199660574; called by muse, mutect2, varscan2
- CELF4 | c.1386G>A p.M462I | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100611836; called by muse, mutect2
- CEP78 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99450741; called by muse, mutect2, varscan2
- CNGA3 | c.1712T>C p.I571T | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as rs750456621, COSV99737125; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN2 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1330386390, COSV59351376; called by muse, mutect2, varscan2
- COG6 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62998046; called by muse, mutect2
- COL11A1 | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs202011565, COSV100617779, COSV62188831; called by muse, mutect2, varscan2
- COL7A1 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.867); catalogued as COSV100096970; called by muse, mutect2, varscan2
- CRBN | c.338T>C p.L113S | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99214252; called by muse, mutect2
- CTNND2 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as COSV100479151; called by muse, mutect2, varscan2
- CUBN | c.4958C>T p.A1653V | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs753664757, COSV64708850; called by muse, mutect2, varscan2
- CYB5D1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99641933; called by muse, mutect2
- DDC | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as COSV100779628; called by muse, mutect2, varscan2
- DISC1 | c.686G>A p.C229Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs1163357667, COSV54422138, COSV99698259; called by muse, mutect2, varscan2
- DNAJB13 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV100135123; called by muse, mutect2
- DNALI1 | c.769G>A p.E257K (on ENST00000296218; = p.E235K on NM_003462.5) | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV99953694; called by muse, mutect2
- DOCK7 | c.3427C>A p.P1143T (on ENST00000635253 / NM_001367561.1; = p.P1112T on NM_033407.3) | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.917); catalogued as COSV52006012, COSV99225267; called by muse, mutect2
- DPYSL3 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs933190174, COSV100575261; called by muse, mutect2
- ENPP1 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 9/93 reads (10%) | catalogued as COSV100719606; called by muse, mutect2, varscan2
- EP300 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54325483, COSV54345374; called by muse, mutect2, varscan2
- EP400 | c.4015G>A p.E1339K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs746305967, COSV100201782; called by muse, mutect2
- ERBB4 | c.1718G>A p.G573D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99628686; called by muse, mutect2
- EXTL3 | c.357G>C p.K119N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99594188; called by muse, mutect2, varscan2
- FAM83G | c.1604C>T p.P535L | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100525338; called by muse, mutect2
- FAM9A | c.964A>C p.I322L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV101121363; called by muse, mutect2, varscan2
- GOLGA3 | c.3092G>A p.G1031D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.168); catalogued as COSV99212231; called by muse, mutect2, varscan2
- GPD2 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs115026480, COSV100133468; called by muse, mutect2
- GPR26 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.453); catalogued as rs200070620, COSV52935578; called by muse, mutect2, varscan2
- H2BC9 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); catalogued as COSV55099491, COSV55099681; called by muse, mutect2
- IQCH | c.451C>A p.H151N | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100246140; called by muse, mutect2, varscan2
- JADE3 | c.1464G>C p.M488I | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99510077; called by muse, mutect2
- KIF26B | c.3839C>T p.S1280F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100832953, COSV63639071; called by muse, mutect2
- LRRC56 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99530537; called by muse, mutect2
- MADD | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.069); catalogued as rs759601036, COSV60621718; called by muse, mutect2, varscan2
- MAP7D2 | c.1562A>C p.Q521P | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV101107456; called by muse, mutect2, varscan2
- MARCHF6 | c.2297G>C p.G766A | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV99929997; called by muse, mutect2
- MGAT3 | c.1147C>G p.R383G | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV100361996, COSV100362078; called by muse, mutect2, varscan2
- MKI67 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100896018, COSV100896830; called by muse, mutect2, varscan2
- MRTO4 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 21/278 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100367518; called by muse, mutect2
- MTCL1 | c.1225G>C p.E409Q (on ENST00000306329 / NM_001378206.1; = p.E49Q on NM_015210.4) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100095188, COSV60411153; called by muse, mutect2, varscan2
- MYO1D | c.785A>T p.E262V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs1395763567, COSV100554660; called by muse, mutect2, varscan2
- NANOS3 | c.491C>T p.S164L (on ENST00000397555; = p.S183L on NM_001098622.2) | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as rs775855231, COSV59249204; called by muse, mutect2, varscan2
- NCAM1 | c.1204G>A p.G402S (on ENST00000316851 / NM_181351.5; = p.G392S on NM_000615.7) | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1037743906, COSV57520177; called by muse, mutect2
- NEDD4 | c.2297C>T p.S766L (on ENST00000508342 / NM_001284338.1; = p.S347L on NM_006154.4) | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV100163937; called by muse, mutect2
- NLRP7 | c.1402C>T p.H468Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as COSV100053062; called by muse, mutect2
- NOTCH1 | c.5920C>T p.Q1974* | Nonsense Mutation (SNP) | VAF 21/130 reads (16%) | catalogued as COSV99490004; called by muse, mutect2, varscan2
- NOTCH2 | c.3260G>A p.C1087Y | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99865563; called by muse, mutect2, varscan2
- NOTCH2 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | catalogued as COSV99865565; called by muse, mutect2
- OGDHL | c.1670A>G p.Y557C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100934432; called by muse, mutect2, varscan2
- OR1J2 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.105); catalogued as rs200185396, COSV100093162; called by muse, mutect2, varscan2
- PASD1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.148); catalogued as COSV64856909; called by muse, mutect2
- PATJ | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs1207663906, COSV100334584, COSV57158872; called by muse, mutect2, varscan2
- PCDH11Y | c.2606G>A p.R869H (on ENST00000400457 / NM_032973.2; = p.R858H on NM_032971.3) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as rs769480066, COSV99292174; called by muse, mutect2, varscan2
- PCDHGA7 | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.917); catalogued as COSV99542641; called by muse, mutect2
- PDLIM5 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); catalogued as rs1026261662, COSV100524085; called by muse, mutect2, varscan2
- PKN1 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99661599; called by muse, mutect2
- POMGNT1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 41/282 reads (15%) | PolyPhen benign (0); catalogued as rs770634205, COSV100915725, COSV64340365; called by muse, mutect2, varscan2
- POU2F3 | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99501327; called by muse, mutect2, varscan2
- PSD | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99193056; called by muse, mutect2
- PXMP2 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs373882774; called by muse, mutect2
- QRICH2 | c.2806C>T p.L936F | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.483); catalogued as COSV99429470; called by muse, mutect2
- RAVER2 | c.1688C>G p.S563C (on ENST00000294428 / NM_001366165.1; = p.S550C on NM_018211.4) | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV99604655, COSV99605441; called by muse, mutect2
- ROR1 | c.2258C>G p.S753* | Nonsense Mutation (SNP) | VAF 5/80 reads (6%) | catalogued as COSV100935431; called by muse, mutect2
- RP1 | c.5884A>G p.T1962A | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99608275; called by muse, mutect2
- RUNX2 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as rs763466386, CD992745; called by muse, mutect2
- RXRA | c.1262G>A p.R421H | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258357952; called by muse, mutect2
- SAMD4B | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as rs571162695, COSV100080504; called by muse, mutect2, varscan2
- SLC29A1 | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100505861; called by muse, mutect2
- SLC46A3 | c.1160G>A p.C387Y | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV57180588; called by muse, mutect2
- SMC1B | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100663384; called by muse, mutect2
- STRADB | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV99524677; called by muse, mutect2, varscan2
- STXBP5L | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs759435411, COSV56524943; called by mutect2, varscan2
- SUPT16H | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs773189447, COSV52848198; called by muse, mutect2, varscan2
- SYNE1 | c.3073G>C p.D1025H (on ENST00000367255 / NM_182961.4; = p.D1032H on NM_033071.3) | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV99550278, COSV99572740; called by muse, mutect2
- TLK2 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.176); catalogued as COSV100409404; called by muse, mutect2
- UBXN4 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1249264657, COSV55635728; called by muse, mutect2, varscan2
- USP6NL | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV99509915; called by muse, mutect2, varscan2
- WASHC2C | c.3529G>A p.E1177K (on ENST00000336378; = p.E1156K on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs1389142717; called by muse, mutect2
- Z83844.2 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.371); catalogued as COSV100379273; called by muse, mutect2, varscan2
- ZMYM3 | c.826G>A p.D276N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV100078156; called by muse, mutect2
- ZNF225 | c.807C>A p.F269L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99489539; called by muse, mutect2, varscan2
- ZNF251 | c.1916C>T p.P639L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99478689; called by muse, mutect2, varscan2
- ZNF521 | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 8/131 reads (6%) | catalogued as COSV100832840; called by muse, mutect2
- GDF2 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.015); called by muse, mutect2
- RBP3 | c.1977G>C p.Q659H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2
- RBP3 | c.2932G>C p.E978Q | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ADAMTS7 | c.156C>T p.D52= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as rs986714527, COSV66309070; called by muse, mutect2
- AP4M1 | c.390G>A p.L130= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs753736268, COSV100385060; called by muse, mutect2, varscan2
- ATP6V0A4 | c.6G>A p.V2= | Silent (SNP) | VAF 16/191 reads (8%) | catalogued as rs749138864, COSV59473499; called by muse, mutect2
- CDC42BPA | c.1782G>A p.Q594= | Silent (SNP) | VAF 18/258 reads (7%) | catalogued as COSV100506173; called by muse, mutect2
- DYTN | c.1041G>A p.Q347= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV101510882; called by muse, mutect2, varscan2
- ESRRG | c.1194G>T p.A398= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV63156261, COSV63175225; called by muse, mutect2, varscan2
- FAM71F1 | c.304C>T p.L102= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV59375266; called by muse, mutect2, varscan2
- FLCN | c.1107C>T p.L369= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs786202175, COSV99550570; ClinVar: likely benign; called by muse, mutect2, varscan2
- GFRA3 | c.624C>T p.A208= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs754570944, COSV51229451; called by muse, mutect2, varscan2
- GRK2 | c.1233G>A p.V411= | Silent (SNP) | VAF 17/168 reads (10%) | catalogued as rs767326527, COSV100419718; called by muse, mutect2
- GTPBP4 | c.1650T>C p.T550= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV99479257; called by muse, mutect2
- HAUS5 | c.1857G>A p.L619= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs1377169701, COSV99178783; called by muse, mutect2, varscan2
- HFE | c.918C>T p.V306= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100352643; called by muse, mutect2
- HK3 | c.1992G>A p.T664= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs554140413, COSV52840310; called by muse, mutect2
- ICAM1 | c.801C>T p.N267= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs777348143, COSV99321010; called by muse, mutect2
- ITGB4 | c.1623C>T p.F541= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99564385; called by muse, mutect2, varscan2
- KIAA1109 | c.3795G>A p.E1265= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs939769113, COSV99167851; called by muse, mutect2, varscan2
- KRTAP15-1 | c.294A>T p.G98= | Silent (SNP) | VAF 13/169 reads (8%) | catalogued as COSV100481639; called by muse, mutect2
- LARGE2 | c.2043C>G p.T681= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV99138914; called by muse, mutect2
- LRIT3 | c.1572G>T p.G524= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV100015884, COSV100016300; called by muse, mutect2, varscan2
- MAST4 | c.6489G>A p.P2163= (on ENST00000403625 / NM_001164664.2; = p.P1974= on NM_015183.3) | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs750408242, COSV99844049; called by muse, mutect2
- MEOX2 | c.471G>A p.A157= | Silent (SNP) | VAF 18/232 reads (8%) | catalogued as COSV100012357; called by muse, mutect2
- NUP54 | c.492C>T p.F164= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99345401; called by muse, mutect2
- OR51A4 | c.432C>T p.A144= | Silent (SNP) | VAF 37/242 reads (15%) | catalogued as COSV100985306; called by muse, mutect2, varscan2
- PCDHB9 | c.2130G>A p.A710= | Silent (SNP) | VAF 30/331 reads (9%) | catalogued as rs1554283357; called by muse, mutect2
- PHC2 | c.784C>T p.L262= | Silent (SNP) | VAF 8/145 reads (6%) | catalogued as COSV99931234; called by muse, mutect2
- PODN | c.492C>T p.L164= (on ENST00000395871; = p.L116= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100439710, COSV100439899; called by muse, mutect2
- PPP1R14B | c.443G>A p.*148= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100501817; called by muse, mutect2
- RBM4 | c.165G>A p.L55= | Silent (SNP) | VAF 25/238 reads (11%) | catalogued as COSV100029689; called by muse, mutect2, varscan2
- RIOK2 | c.1503G>A p.V501= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV99300121; called by muse, mutect2
- SERPINA10 | c.1158A>C p.T386= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV100003934; called by muse, mutect2, varscan2
- SF3B1 | c.9G>A p.K3= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as rs1417266098, COSV100135248; called by muse, mutect2
- SLC6A8 | c.1662G>A p.P554= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs149677083, COSV99466100; ClinVar: likely benign / benign; called by mutect2, varscan2
- SPEG | c.8955G>A p.E2985= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100405117; called by muse, mutect2, varscan2
- SUPT16H | c.2649G>A p.K883= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99360047, COSV99360096; called by muse, varscan2
- TNNI2 | c.204G>A p.L68= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99425548; called by muse, mutect2
- TRMT9B | c.618G>A p.Q206= | Silent (SNP) | VAF 12/135 reads (9%) | catalogued as COSV101501633; called by muse, mutect2
- TRPM2 | c.2376C>T p.F792= | Silent (SNP) | VAF 18/224 reads (8%) | catalogued as rs1228659456, COSV55966308; called by muse, mutect2
- TUBA1A | c.351C>T p.L117= | Silent (SNP) | VAF 20/181 reads (11%) | catalogued as rs749139359, COSV55497324, COSV99853775; called by muse, mutect2, varscan2
- ZNF44 | c.894G>A p.E298= (on ENST00000356109 / NM_001164276.2; = p.E250= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 10/164 reads (6%) | catalogued as COSV61135153; called by muse, mutect2
- ZNF544 | c.1083A>G p.K361= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs956159977, COSV99517155; called by muse, mutect2, varscan2
- NR1D1 | c.-1C>T | 5'UTR (SNP) | VAF 14/76 reads (18%) | catalogued as COSV55858969; called by muse, mutect2, varscan2
- RPL23A | c.26-155G>T | Intron (SNP) | VAF 6/116 reads (5%) | catalogued as COSV99411825; called by muse, mutect2
- SMIM12 | chr1:34855177 C>T | 3'Flank (SNP) | VAF 6/109 reads (6%) | called by muse, mutect2
- TIMM50 | chr19:39480590 C>T | 5'Flank (SNP) | VAF 8/98 reads (8%) | catalogued as rs1402361435, COSV100068003; called by muse, mutect2
